ALCHEMIST case ALCH-ABEI — Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial (ALCHEMIST-ALCH)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/35782fa4-5d72-4b11-934a-34deff0c5df0

Demographics
Sex at birth: male.

Diagnoses (1)
1. Adenocarcinoma, NOS: Age at diagnosis: 78.3 years (28,596 days).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ALCH-ABEI-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Fresh.
- Sample ALCH-ABEI-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ALCH-ABEI-TTP1-A-1-0-S2: Section location: Top; Percent tumor cells: 24; Percent tumor nuclei: 50; Percent normal cells: 18; Percent necrosis: 8; Percent stromal cells: 50; Percent lymphocyte infiltration: 15; Percent monocyte infiltration: 8; Percent neutrophil infiltration: 2.
